Somatic mutation profile of tumor specimen TCGA-AD-6965-01A (aliquot TCGA-AD-6965-01A-11D-1924-10) from TCGA case TCGA-AD-6965, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.6 years (22,853 days).
Specimen TCGA-AD-6965-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81b1751e-f367-482c-8465-92d39062b73c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6965-10A (Blood Derived Normal), aliquot TCGA-AD-6965-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dde5333e-b1a9-44d2-9c9e-5c9e498e76b3

The open-access MAF lists 139 somatic variants for this specimen: 99 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 39, Nonsense Mutation 7, Splice Site 4, Frame Shift Del 4, Splice Region 3, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 38/58 reads (66%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 97/115 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 40/84 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 31/38 reads (82%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200727306, COSV52950306; called by muse, mutect2, varscan2
- ACAN | c.5108G>C p.S1703T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61371240; called by muse, mutect2, varscan2
- ADAMTS14 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs546049764, COSV64607468; called by muse, mutect2
- AFM | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1375065139, COSV56922710; called by muse, mutect2, varscan2
- ANKRD44 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764702362, COSV56552819; called by muse, mutect2, varscan2
- APC | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as CM130051, COSV99964925; called by muse, varscan2
- APLP1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs777735772, COSV55703144; called by muse, mutect2, varscan2
- ASB14 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV67467739; called by muse, mutect2, varscan2
- CBLN4 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV50352486, COSV50354709; called by muse, mutect2, varscan2
- CDC27 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV50709088; called by muse, mutect2, varscan2
- CDC42BPA | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62024805; called by muse, mutect2, varscan2
- CHST2 | c.1010T>A p.V337E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58887402; called by muse, mutect2, varscan2
- CNTN6 | c.943dup p.Y315Lfs*19 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | catalogued as rs1216775937; called by mutect2, pindel, varscan2
- CRACD | c.2026C>A p.L676M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51733948; called by muse, mutect2, varscan2
- CRAT | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs772513852, COSV58876190; called by muse, mutect2, varscan2
- CREB3 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 90/106 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754545426, COSV59212803; called by muse, mutect2, varscan2
- CSMD1 | c.4993T>A p.F1665I (on ENST00000520002; = p.F1664I on NM_033225.6) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100143009; called by muse, mutect2, varscan2
- DGKZ | c.3329G>A p.R1110Q (on ENST00000454345 / NM_001105540.2; = p.R922Q on NM_003646.4) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV100550984; called by muse, mutect2
- DNMT3A | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV53083081; called by muse, mutect2, varscan2
- DPYSL4 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs746836946, COSV58310391; called by muse, mutect2, varscan2
- EFEMP1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as rs1335365938, COSV62614755; called by muse, mutect2, varscan2
- EGFLAM | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV59294193; called by muse, mutect2, varscan2
- ELK1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 59/63 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55952687; called by muse, mutect2, varscan2
- ENO1 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV99318583; called by muse, mutect2, varscan2
- EPHA5 | c.2802G>T p.K934N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56679947; called by muse, varscan2
- EPHA5 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764665078, COSV56630798; called by muse, varscan2
- ESYT1 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs760550478, COSV57274606; called by muse, mutect2, varscan2
- FPR3 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs374026779; called by muse, mutect2, varscan2
- FSTL5 | c.1975G>A p.G659S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1168923472, COSV60237382; called by muse, mutect2, varscan2
- GALNT9 | c.1505G>A p.R502Q (on ENST00000328957 / NM_001122636.2; = p.R136Q on NM_021808.3) | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); catalogued as rs762383807, COSV61104369; called by muse, mutect2, varscan2
- GUCY2F | c.2408A>G p.D803G | Missense Mutation (SNP) | VAF 66/72 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV54309731; called by muse, mutect2, varscan2
- HERC5 | c.389+1G>T p.X130_splice | Splice Site (SNP) | VAF 93/171 reads (54%) | catalogued as COSV52046047; called by muse, mutect2, varscan2
- HNF1B | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs753701914; called by muse, mutect2, varscan2
- INTS11 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1170629459, COSV60088879, COSV60089890; called by muse, mutect2, varscan2
- IRS4 | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.05); catalogued as COSV64536498; called by muse, mutect2, varscan2
- KCNA1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV66838110; called by muse, mutect2
- KCNG4 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200888782; called by muse, mutect2, varscan2
- KIF4B | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 48/184 reads (26%) | catalogued as rs200206658, COSV70528996; called by muse, mutect2, varscan2
- KRTAP6-1 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 82/160 reads (51%) | PolyPhen probably damaging (0.98); catalogued as COSV58169140; called by muse, mutect2, varscan2
- MAP2 | c.2380G>T p.D794Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV52280755, COSV52307424; called by muse, mutect2, varscan2
- MEIS1 | c.717C>G p.H239Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55493556; called by muse, mutect2, varscan2
- MSR1 | c.981A>C p.G327= | Splice Region (SNP) | VAF 24/30 reads (80%) | catalogued as COSV50542748; called by muse, mutect2, varscan2
- MTNR1B | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as rs777351825, COSV57065883; called by muse, mutect2, varscan2
- MYLK2 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV101044640, COSV65659980; called by muse, mutect2, varscan2
- MYO5A | c.2003T>C p.F668S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100697257; called by muse, mutect2, varscan2
- MYO9B | c.1988T>A p.L663Q | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68283376; called by muse, mutect2, varscan2
- NADSYN1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs551641223, COSV100034405; called by muse, mutect2, varscan2
- NCAPD3 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV73259057; called by muse, mutect2, varscan2
- NFATC1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs367652299, COSV53695271; called by muse, mutect2, varscan2
- NID2 | c.3091G>A p.G1031S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs556301909, COSV53494364; called by muse, mutect2, varscan2
- NOTCH1 | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53068063, COSV53102169; called by muse, mutect2, varscan2
- NTNG2 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1162177647, COSV62369410; called by muse, mutect2, varscan2
- NUDT7 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV51747452; called by muse, mutect2, varscan2
- NUGGC | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1461509103, COSV58437128, COSV58440180; called by muse, mutect2, varscan2
- OLFM1 | c.1232C>T p.T411M (on ENST00000371793 / NM_001282611.2; = p.T393M on NM_014279.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767622547, COSV53277197, COSV53278980; called by muse, mutect2, varscan2
- OMD | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 110/178 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs776018014, COSV65020450; called by muse, mutect2, varscan2
- OSR2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV52559561; called by muse, mutect2, varscan2
- PCDH17 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as rs768302880, COSV100931400; called by muse, mutect2, varscan2
- PCDHGB4 | c.1768G>C p.V590L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54053191; called by muse, mutect2
- PEAR1 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs146753859; called by muse, mutect2, varscan2
- PGM1 | c.874-1G>T p.X292_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV64300021, COSV64301119; called by muse, mutect2, varscan2
- PLCB4 | c.2873G>T p.C958F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.974); catalogued as COSV53821960; called by muse, mutect2, varscan2
- PLK4 | c.2563-1G>C p.X855_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV54639914; called by muse, mutect2, varscan2
- POLR3E | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100241885; called by muse, mutect2, varscan2
- PRG4 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV66626138; called by muse, mutect2, varscan2
- PTK7 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs766748291, COSV57852368; called by muse, mutect2, varscan2
- RBM10 | c.2119C>T p.Q707* | Nonsense Mutation (SNP) | VAF 31/34 reads (91%) | catalogued as COSV61310779; called by muse, mutect2, varscan2
- RHOA | c.275_276del p.L92* | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | catalogued as COSV69043835; called by mutect2, pindel, varscan2
- RHOU | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.352); catalogued as rs764760417, COSV64209313; called by muse, mutect2, varscan2
- RRAD | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55337225; called by muse, mutect2, varscan2
- RSPH3 | c.1123-1G>T p.X375_splice (on ENST00000252655; = p.X233_splice on NM_031924.8) | Splice Site (SNP) | VAF 41/188 reads (22%) | catalogued as COSV51925232; called by muse, mutect2, varscan2
- SCN7A | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs559936352, COSV101313343, COSV69270088; called by muse, mutect2, varscan2
- SCN9A | c.4502G>C p.G1501A (on ENST00000303354; = p.G1490A on NM_002977.3) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV57618828, COSV99069735; called by muse, mutect2, varscan2
- SH3BP2 | c.429C>T p.S143= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs140532510, COSV100696853; called by muse, mutect2, varscan2
- SLC10A3 | c.1219del p.L407* | Frame Shift Del (DEL) | VAF 64/94 reads (68%) | catalogued as COSV54837721; called by mutect2, pindel, varscan2
- SLC7A1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV66332156; called by muse, mutect2, varscan2
- SNPH | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs373195415; called by muse, mutect2, varscan2
- SYN3 | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751035542, COSV100248230; called by muse, mutect2, varscan2
- TAAR5 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs557518982, COSV57800058; called by muse, mutect2, varscan2
- TEP1 | c.4526G>A p.G1509E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV53001961; called by muse, mutect2, varscan2
- TFB1M | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as rs377038349; called by muse, mutect2, varscan2
- THBS2 | c.2780G>T p.G927V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64682693; called by muse, mutect2, varscan2
- TMC4 | c.605A>G p.D202G (on ENST00000617472 / NM_001145303.3; = p.D196G on NM_144686.4) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1284377716, COSV55478134; called by muse, mutect2, varscan2
- TRPC3 | c.920C>T p.P307L (on ENST00000379645 / NM_001366479.2; = p.P234L on NM_003305.2) | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756858799, COSV53381147, COSV53384223; called by muse, mutect2, varscan2
- TTC16 | c.2593C>A p.Q865K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV60162499; called by muse, mutect2, varscan2
- VWCE | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV57116048; called by muse, mutect2, varscan2
- WDR44 | c.1854C>T p.N618= | Splice Region (SNP) | VAF 71/166 reads (43%) | catalogued as COSV54170441; called by muse, mutect2, varscan2
- ZKSCAN2 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60159253; called by muse, mutect2, varscan2
- ZNF579 | c.1537T>A p.S513T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as COSV57639068; called by muse, mutect2, varscan2
- ZNF599 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 177/197 reads (90%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1439322587, COSV61397772; called by muse, mutect2, varscan2
- ZNF667 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs754470431, COSV52634143; called by muse, mutect2, varscan2
- NHLRC2 | c.1523dup p.N508Kfs*13 | Frame Shift Ins (INS) | VAF 49/150 reads (33%) | called by mutect2, pindel, varscan2
- PNN | c.224_227del p.K75Rfs*42 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- PRSS54 | c.321_324del p.H107Qfs*19 | Frame Shift Del (DEL) | VAF 65/161 reads (40%) | called by mutect2, pindel, varscan2
- SPEN | c.5363A>G p.N1788S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- ADCY8 | c.807C>T p.D269= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV53925683; called by muse, mutect2, varscan2
- ANK2 | c.11616C>T p.D3872= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as rs768755447, COSV52180742; called by muse, mutect2, varscan2
- BMS1 | c.2847G>A p.R949= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as rs774653178, COSV65734184, COSV65735821; called by muse, mutect2, varscan2
- BST2 | c.102C>T p.I34= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1408717756, COSV53089403; called by muse, mutect2, varscan2
- CHD5 | c.3570C>T p.D1190= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as rs767408616, COSV52407751; called by muse, mutect2, varscan2
- CMYA5 | c.6654T>C p.D2218= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV71410372; called by muse, mutect2, varscan2
- COL5A1 | c.1788G>A p.V596= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV65676351; called by muse, mutect2, varscan2
- FBLIM1 | c.1080C>T p.C360= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1385692912, COSV60032093; called by muse, mutect2, varscan2
- FCER2 | c.684G>A p.L228= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs866995831, COSV60917813; called by muse, mutect2, varscan2
- FMO5 | c.87T>C p.P29= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1169259366, COSV99566624; called by muse, varscan2
- FOXG1 | c.1335G>A p.P445= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV57395563; called by muse, mutect2, varscan2
- FRMPD2 | c.339C>A p.L113= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV59724667; called by muse, mutect2, varscan2
- FRYL | c.8499A>G p.R2833= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV51964856; called by muse, mutect2, varscan2
- GABRA1 | c.87G>T p.P29= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV50124468; called by muse, mutect2
- INO80 | c.2247A>G p.K749= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- INVS | c.2685C>T p.P895= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs371932940; called by muse, mutect2, varscan2
- KCNC2 | c.606C>T p.D202= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as rs199945851, COSV54382284; called by muse, mutect2, varscan2
- MGAM | c.4416C>T p.D1472= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs751737247, COSV72075382; called by muse, mutect2, varscan2
- MYO3A | c.2985T>C p.A995= | Silent (SNP) | VAF 70/171 reads (41%) | catalogued as rs1432895044, COSV56353064; called by muse, mutect2, varscan2
- OR4K5 | c.339G>T p.V113= | Silent (SNP) | VAF 27/227 reads (12%) | catalogued as COSV60002929; called by muse, mutect2, varscan2
- OTOF | c.5694C>T p.N1898= (on ENST00000272371 / NM_194248.3; = p.N1131= on NM_004802.4) | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs1318486079, COSV55506552; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA8 | c.1362G>A p.A454= | Silent (SNP) | VAF 71/109 reads (65%) | catalogued as COSV65337296; called by muse, mutect2, varscan2
- PCDHGA6 | c.1347G>A p.P449= | Silent (SNP) | VAF 34/51 reads (67%) | catalogued as rs757761874, COSV53908918; called by muse, mutect2, varscan2
- PCDHGA7 | c.1404G>A p.G468= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1199465212; called by muse, mutect2
- PIDD1 | c.2199C>T p.P733= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs774016396, COSV57195362; called by muse, mutect2, varscan2
- PNCK | c.642C>T p.D214= (on ENST00000340888 / NM_001366975.1; = p.D297= on NM_001039582.3) | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs782262921, COSV100562140; called by muse, mutect2
- POU4F3 | c.492G>A p.P164= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV57945311; called by muse, mutect2, varscan2
- PPARA | c.228G>A p.S76= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as rs774377701, COSV53081958; called by muse, mutect2, varscan2
- PREX1 | c.2883G>A p.P961= | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as rs368665525, COSV64255201; called by muse, mutect2, varscan2
- RBMXL2 | c.144G>A p.S48= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV60979063; called by muse, mutect2, varscan2
- SCN8A | c.1581G>A p.K527= | Silent (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- SHANK1 | c.5148C>T p.A1716= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs760790394, COSV53264841; called by muse, mutect2, varscan2
- SORCS3 | c.2238C>A p.V746= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV63794004; called by muse, mutect2, varscan2
- STK16 | c.813G>A p.S271= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs766349692, COSV50284186; called by muse, mutect2, varscan2
- TTC31 | c.1425A>T p.S475= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV52037624; called by muse, mutect2, varscan2
- VMO1 | c.558C>T p.L186= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs1453519595, COSV54498320; called by muse, mutect2, varscan2
- ZC3H7A | c.666G>A p.P222= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs762637256, COSV63271704; called by muse, mutect2, varscan2
- ZFHX3 | c.9654G>A p.P3218= | Silent (SNP) | VAF 97/200 reads (49%) | catalogued as rs374377988, COSV51740193; called by muse, mutect2, varscan2
- ZSWIM8 | c.5355C>T p.D1785= (on ENST00000605216 / NM_001242487.2; = p.D1790= on NM_015037.3) | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs771281686, COSV55218716; called by muse, mutect2, varscan2
- DCHS2 | n.2470C>T | RNA (SNP) | VAF 40/65 reads (62%) | catalogued as rs557854971, COSV59741625; called by muse, mutect2, varscan2
